Somatic mutation profile of tumor specimen TCGA-EB-A5FP-01A (aliquot TCGA-EB-A5FP-01A-11D-A27K-08) from TCGA case TCGA-EB-A5FP, project TCGA-SKCM (Skin Cutaneous Melanoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; Age at diagnosis: 65.3 years (23,844 days).
Specimen TCGA-EB-A5FP-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b5a867e1-549a-4322-bf50-40cd139f3a41.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-EB-A5FP-10A (Blood Derived Normal), aliquot TCGA-EB-A5FP-10A-01D-A27N-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f726c117-fdcf-4678-8c4b-df324f841f0f

The open-access MAF lists 483 somatic variants for this specimen: 311 protein-altering or splice-affecting, 162 silent, 10 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 284, Silent 162, Nonsense Mutation 18, Splice Site 5, Intron 4, RNA 3, Splice Region 2, 5'Flank 1, Frame Shift Del 1, 5'UTR 1, In Frame Del 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 70/121 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- BRAF | c.1918G>A p.V640M (on ENST00000288602 / NM_001374244.1; = p.V600M on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 70/120 reads (58%) | SIFT deleterious (0); PolyPhen possibly damaging (0.737); catalogued as rs121913378, COSV56066607, COSV56075762, COSV56124012, COSV56152883; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- CYBB | c.469C>T p.R157* | Nonsense Mutation (SNP) | VAF 38/82 reads (46%) | catalogued as rs886039335, CM940323, COSV101059774; ClinVar: pathogenic; called by muse, mutect2, varscan2
- MAP2K1 | c.371C>T p.P124L | Missense Mutation (SNP) | VAF 47/110 reads (43%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs397516792, CM071852, CM073191, COSV61068422, COSV61068985, COSV61070219; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.637C>T p.R213* | Nonsense Mutation (SNP) | VAF 35/41 reads (85%) | hotspot (GDC flag); catalogued as rs397516436, CM951226, COSV52665560, COSV52740638, COSV52746781, COSV52782151; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP63 | c.1135C>T p.R379C | Missense Mutation (SNP) | VAF 27/66 reads (41%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs761885185, COSV53196562, COSV53210463; called by muse, mutect2, varscan2
- ABCC1 | c.2294G>A p.G765D | Missense Mutation (SNP) | VAF 60/141 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100579772; called by muse, mutect2, varscan2
- ABCC5 | c.2227C>T p.Q743* | Nonsense Mutation (SNP) | VAF 53/134 reads (40%) | catalogued as COSV99657032; called by muse, mutect2, varscan2
- ABLIM2 | c.1228C>T p.P410S (on ENST00000341937 / NM_001130084.2; = p.P443S on NM_001130083.2) | Missense Mutation (SNP) | VAF 23/60 reads (38%) | SIFT tolerated (0.35); PolyPhen benign (0); catalogued as COSV99589776; called by muse, mutect2, varscan2
- ACE | c.3107A>G p.N1036S | Missense Mutation (SNP) | VAF 26/67 reads (39%) | SIFT deleterious (0.03); PolyPhen benign (0.094); catalogued as COSV99327231; called by muse, mutect2, varscan2
- ACP2 | c.463C>T p.P155S | Missense Mutation (SNP) | VAF 22/66 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99922280; called by muse, mutect2, varscan2
- ACSM4 | c.672G>A p.M224I | Missense Mutation (SNP) | VAF 5/24 reads (21%) | SIFT deleterious (0.04); PolyPhen benign (0.411); catalogued as COSV101257194; called by muse, mutect2, varscan2
- ADAM7 | c.1670G>A p.G557E | Missense Mutation (SNP) | VAF 4/43 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51545602, COSV99443048; called by muse, mutect2, varscan2
- ADAM7 | c.2197C>T p.H733Y | Missense Mutation (SNP) | VAF 32/47 reads (68%) | SIFT deleterious (0.04); PolyPhen benign (0.003); catalogued as rs867658404, COSV51536214; called by muse, mutect2, varscan2
- ADAMTSL4 | c.845G>A p.R282Q | Missense Mutation (SNP) | VAF 41/79 reads (52%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as rs150503018, COSV55001451, COSV99647395; called by muse, mutect2, varscan2
- ADCY8 | c.2426T>A p.F809Y | Missense Mutation (SNP) | VAF 8/19 reads (42%) | SIFT tolerated (0.75); PolyPhen benign (0.177); catalogued as COSV99652687; called by muse, mutect2, varscan2
- ADGRF5 | c.214G>A p.E72K | Missense Mutation (SNP) | VAF 31/88 reads (35%) | SIFT tolerated (0.4); PolyPhen possibly damaging (0.471); catalogued as COSV99345776; called by muse, mutect2, varscan2
- ADGRG3 | c.1444C>T p.L482F | Missense Mutation (SNP) | VAF 46/98 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100342456; called by muse, mutect2, varscan2
- ADGRL3 | c.1283C>T p.S428L (on ENST00000506720 / NM_001322402.2; = p.S360L on NM_015236.6) | Missense Mutation (SNP) | VAF 28/45 reads (62%) | SIFT deleterious (0.04); PolyPhen benign (0.411); catalogued as COSV101547105, COSV72265283; called by muse, mutect2, varscan2
- ADPRH | c.199C>T p.L67F | Missense Mutation (SNP) | VAF 37/90 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100813327; called by muse, mutect2, varscan2
- AK7 | c.1039G>A p.G347R | Missense Mutation (SNP) | VAF 23/53 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99967334; called by muse, mutect2, varscan2
- ALDH1L2 | c.2224G>A p.D742N | Missense Mutation (SNP) | VAF 14/31 reads (45%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.665); catalogued as rs1327603933, COSV99311108; called by muse, mutect2, varscan2
- ALPK2 | c.4825C>T p.P1609S | Missense Mutation (SNP) | VAF 36/83 reads (43%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.829); catalogued as COSV100864136; called by muse, mutect2, varscan2
- ALPP | c.533C>T p.P178L | Missense Mutation (SNP) | VAF 12/62 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1428516218, COSV101235159; called by muse, mutect2, varscan2
- AMOT | c.2516C>T p.S839F (on ENST00000371959 / NM_001113490.1; = p.S430F on NM_133265.3) | Missense Mutation (SNP) | VAF 43/103 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1355108884, COSV100495191; called by muse, mutect2, varscan2
- ANKS1B | c.890C>T p.P297L | Missense Mutation (SNP) | VAF 10/31 reads (32%) | SIFT tolerated (0.05); PolyPhen benign (0); catalogued as rs1390785746, COSV100246196; called by muse, mutect2, varscan2
- ARAP2 | c.3679G>A p.A1227T | Missense Mutation (SNP) | VAF 26/81 reads (32%) | SIFT tolerated (0.83); PolyPhen benign (0.001); catalogued as COSV100394789, COSV58288491; called by muse, mutect2, varscan2
- ARFGEF1 | c.2356G>A p.E786K | Missense Mutation (SNP) | VAF 15/40 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.851); catalogued as COSV99142706; called by muse, mutect2, varscan2
- ARHGAP31 | c.2315G>A p.G772E | Missense Mutation (SNP) | VAF 12/97 reads (12%) | SIFT tolerated (0.26); PolyPhen benign (0.007); catalogued as rs745963681, COSV99957241; called by muse, mutect2, varscan2
- ARMC3 | c.937C>T p.H313Y | Missense Mutation (SNP) | VAF 7/11 reads (64%) | SIFT deleterious (0); PolyPhen possibly damaging (0.646); catalogued as COSV99958309; called by muse, mutect2, varscan2
- ARMC4 | c.2945C>T p.A982V | Missense Mutation (SNP) | VAF 45/64 reads (70%) | SIFT deleterious (0); PolyPhen probably damaging (0.929); catalogued as rs758192226, COSV59466081; called by muse, mutect2, varscan2
- ASIC5 | c.137C>T p.S46F | Missense Mutation (SNP) | VAF 25/79 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.833); catalogued as COSV101539759; called by muse, mutect2, varscan2
- ASXL3 | c.715G>A p.G239R | Missense Mutation (SNP) | VAF 7/22 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV99325243; called by muse, mutect2, varscan2
- ATP10D | c.2341G>A p.V781I | Missense Mutation (SNP) | VAF 47/114 reads (41%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.992); catalogued as COSV99905719; called by muse, mutect2, varscan2
- B3GAT1 | c.644C>T p.S215F | Missense Mutation (SNP) | VAF 6/13 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1301728193, COSV100437710, COSV56999527; called by muse, mutect2
- BCL11B | c.2386G>A p.D796N (on ENST00000357195 / NM_001282237.2; = p.D725N on NM_022898.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 8/21 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61737153; called by muse, mutect2, varscan2
- BCL2 | c.692C>T p.T231I | Missense Mutation (SNP) | VAF 23/51 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100384770; called by muse, mutect2, varscan2
- BEND2 | c.97G>A p.E33K | Missense Mutation (SNP) | VAF 14/39 reads (36%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.283); catalogued as COSV101192073; called by muse, mutect2, varscan2
- C1orf158 | c.23C>T p.P8L | Missense Mutation (SNP) | VAF 25/63 reads (40%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.86); catalogued as COSV99847336; called by muse, mutect2, varscan2
- C22orf42 | c.124G>A p.A42T | Missense Mutation (SNP) | VAF 69/208 reads (33%) | SIFT tolerated, low confidence (0.05); PolyPhen possibly damaging (0.682); catalogued as COSV101173335; called by muse, mutect2, varscan2
- CACNA2D3 | c.3157G>A p.E1053K | Missense Mutation (SNP) | VAF 15/46 reads (33%) | SIFT tolerated (0.19); PolyPhen benign (0.15); catalogued as COSV55557579; called by muse, mutect2, varscan2
- CALD1 | c.1928C>T p.S643F (on ENST00000361675 / NM_033138.4; = p.S388F on NM_004342.7) | Missense Mutation (SNP) | VAF 59/111 reads (53%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.965); catalogued as COSV100724316, COSV62648191; called by muse, mutect2, varscan2
- CATIP | c.229G>A p.E77K | Missense Mutation (SNP) | VAF 11/59 reads (19%) | SIFT tolerated (0.07); PolyPhen benign (0.08); catalogued as COSV99179558; called by muse, mutect2, varscan2
- CCDC174 | c.1112C>T p.S371F | Missense Mutation (SNP) | VAF 19/38 reads (50%) | SIFT tolerated (0.32); PolyPhen benign (0.296); catalogued as rs866411473, COSV53783586; called by muse, mutect2, varscan2
- CCDC60 | c.851C>T p.S284L | Missense Mutation (SNP) | VAF 44/147 reads (30%) | SIFT deleterious (0.04); PolyPhen benign (0.024); catalogued as rs970650146, COSV100555268; called by muse, mutect2, varscan2
- CCDC88B | c.2860C>T p.Q954* | Nonsense Mutation (SNP) | VAF 4/16 reads (25%) | catalogued as COSV100105546; called by muse, mutect2
- CCNB3 | c.1226G>A p.G409E | Missense Mutation (SNP) | VAF 56/111 reads (50%) | SIFT tolerated (0.85); PolyPhen benign (0.007); catalogued as COSV99329238; called by muse, mutect2, varscan2
- CD300LG | c.895G>A p.E299K | Missense Mutation (SNP) | VAF 6/27 reads (22%) | SIFT tolerated (0.08); PolyPhen benign (0.018); catalogued as COSV53223169; called by muse, mutect2, varscan2
- CDH18 | c.1253+1G>A p.X418_splice | Splice Site (SNP) | VAF 47/96 reads (49%) | catalogued as COSV99935724; called by muse, mutect2, varscan2
- CDK3 | c.865C>T p.P289S | Missense Mutation (SNP) | VAF 41/75 reads (55%) | SIFT tolerated, low confidence (0.57); PolyPhen benign (0.003); catalogued as rs1387444937, COSV56908335; called by muse, mutect2, varscan2
- CEBPZ | c.1471A>C p.N491H | Missense Mutation (SNP) | VAF 33/64 reads (52%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.764); catalogued as rs1451471673, COSV99135605; called by muse, mutect2, varscan2
- CEP164 | c.3612C>T p.A1204= | Splice Region (SNP) | VAF 20/59 reads (34%) | catalogued as rs1037628497, COSV99633605; called by muse, mutect2, varscan2
- CEPT1 | c.53C>T p.S18F | Missense Mutation (SNP) | VAF 47/82 reads (57%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0); catalogued as COSV100853486; called by muse, mutect2, varscan2
- CHGB | c.1861C>T p.P621S | Missense Mutation (SNP) | VAF 21/40 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100972979, COSV66760839; called by muse, mutect2, varscan2
- CHIA | c.34C>T p.L12F | Missense Mutation (SNP) | VAF 76/204 reads (37%) | SIFT tolerated (0.12); PolyPhen benign (0.042); catalogued as rs771419256, COSV100588561, COSV100588711; called by muse, mutect2, varscan2
- CHRNA7 | c.513G>A p.W171* | Nonsense Mutation (SNP) | VAF 22/24 reads (92%) | catalogued as COSV100181351; called by mutect2, varscan2
- COL11A1 | c.3505G>A p.E1169K | Missense Mutation (SNP) | VAF 23/61 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); catalogued as COSV62195749; called by muse, mutect2, varscan2
- COL11A1 | c.1714C>T p.P572S | Missense Mutation (SNP) | VAF 41/109 reads (38%) | SIFT deleterious (0.03); PolyPhen benign (0.003); catalogued as COSV100617006; called by muse, mutect2, varscan2
- COL12A1 | c.8797G>A p.D2933N | Missense Mutation (SNP) | VAF 173/412 reads (42%) | SIFT tolerated (0.5); PolyPhen benign (0.026); catalogued as COSV100486120; called by muse, mutect2, varscan2
- CPAMD8 | c.2698C>T p.P900S (on ENST00000651564; = p.P853S on NM_015692.5) | Missense Mutation (SNP) | VAF 113/149 reads (76%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.98); catalogued as COSV101488526; called by muse, mutect2, varscan2
- CRYBG1 | c.4030G>A p.D1344N | Missense Mutation (SNP) | VAF 57/71 reads (80%) | SIFT tolerated (0.52); PolyPhen benign (0.012); catalogued as COSV64811002; called by muse, mutect2, varscan2
- CRYGD | c.382G>A p.E128K | Missense Mutation (SNP) | VAF 55/94 reads (59%) | SIFT deleterious (0.02); PolyPhen benign (0.348); catalogued as COSV100006065; called by muse, mutect2, varscan2
- CSF2RB | c.2345A>G p.N782S | Missense Mutation (SNP) | VAF 39/122 reads (32%) | SIFT tolerated (0.16); PolyPhen benign (0.003); catalogued as COSV99453986; called by muse, mutect2, varscan2
- CSF3R | c.533T>G p.V178G | Missense Mutation (SNP) | VAF 43/87 reads (49%) | SIFT deleterious (0); PolyPhen possibly damaging (0.702); catalogued as COSV100117824; called by muse, mutect2, varscan2
- CXCR2 | c.194G>A p.G65E | Missense Mutation (SNP) | VAF 80/161 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs773306755, COSV100578978; called by muse, mutect2, varscan2
- CYBB | c.488C>T p.P163L | Missense Mutation (SNP) | VAF 23/53 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV101059775; called by muse, mutect2, varscan2
- CYFIP2 | c.1402G>A p.E468K | Missense Mutation (SNP) | VAF 50/59 reads (85%) | SIFT deleterious (0); PolyPhen possibly damaging (0.893); catalogued as rs866027154, COSV100557100; called by muse, mutect2, varscan2
- CYP21A2 | c.998C>T p.S333F | Missense Mutation (SNP) | VAF 16/96 reads (17%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.949); catalogued as rs1159901869, COSV100926404; called by muse, mutect2, varscan2
- CYP4F8 | c.1525G>A p.E509K | Missense Mutation (SNP) | VAF 6/11 reads (55%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.6); catalogued as COSV100358141; called by muse, mutect2, varscan2
- DACH2 | c.1208C>T p.P403L | Missense Mutation (SNP) | VAF 11/30 reads (37%) | SIFT tolerated (0.11); PolyPhen benign (0.031); catalogued as rs1368471132, COSV64162065; called by muse, mutect2, varscan2
- DAO | c.574G>A p.D192N | Missense Mutation (SNP) | VAF 7/36 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99948691; called by muse, mutect2, varscan2
- DBF4B | c.274C>T p.R92C | Missense Mutation (SNP) | VAF 30/79 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.95); catalogued as rs774276898, COSV59261650; called by muse, mutect2, varscan2
- DCP1A | c.806C>T p.P269L | Missense Mutation (SNP) | VAF 11/42 reads (26%) | SIFT tolerated (0.33); PolyPhen benign (0.003); catalogued as COSV53687481; called by muse, mutect2, varscan2
- DEUP1 | c.1271C>T p.T424I | Missense Mutation (SNP) | VAF 4/9 reads (44%) | SIFT tolerated (0.5); PolyPhen benign (0.079); catalogued as COSV99977249; called by mutect2, varscan2
- DMBT1 | c.3463G>A p.D1155N (on ENST00000338354 / NM_001377530.1; = p.D656N on NM_004406.3) | Missense Mutation (SNP) | VAF 155/239 reads (65%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.482); catalogued as COSV57558691; called by muse, mutect2, varscan2
- DMBX1 | c.479C>T p.T160I | Missense Mutation (SNP) | VAF 45/149 reads (30%) | SIFT deleterious (0.04); PolyPhen benign (0.047); catalogued as rs1160625365, COSV100760804; called by muse, mutect2, varscan2
- DNAH3 | c.9823G>A p.E3275K | Missense Mutation (SNP) | VAF 73/165 reads (44%) | SIFT tolerated (0.42); PolyPhen benign (0.11); catalogued as COSV54523400; called by muse, mutect2, varscan2
- DNAH5 | c.6877C>T p.P2293S | Missense Mutation (SNP) | VAF 29/76 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99450761; called by muse, mutect2, varscan2
- DNAH7 | c.9346G>A p.G3116R | Missense Mutation (SNP) | VAF 8/29 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100415688, COSV100416917; called by muse, mutect2, varscan2
- DNAH9 | c.3806A>C p.E1269A | Missense Mutation (SNP) | VAF 53/122 reads (43%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.902); catalogued as COSV99306310; called by muse, mutect2, varscan2
- DPEP3 | c.1168G>A p.E390K | Missense Mutation (SNP) | VAF 106/225 reads (47%) | SIFT deleterious (0.03); PolyPhen benign (0.142); catalogued as rs747505806, COSV99262748; called by muse, mutect2, varscan2
- DPPA2 | c.809C>T p.S270F | Missense Mutation (SNP) | VAF 29/87 reads (33%) | SIFT deleterious (0.04); PolyPhen benign (0.046); catalogued as COSV101524775, COSV72118156; called by muse, mutect2, varscan2
- DRD2 | c.649C>T p.R217C | Missense Mutation (SNP) | VAF 54/133 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1487691738, COSV60758953; called by muse, mutect2, varscan2
- DSC1 | c.1875T>A p.D625E | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT tolerated (0.07); PolyPhen benign (0.152); catalogued as rs1240499333, COSV99937740; called by muse, mutect2, varscan2
- DSC2 | c.1600G>A p.D534N | Missense Mutation (SNP) | VAF 49/132 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as rs1555638635, COSV51867438, COSV99199683; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DSCAM | c.2990C>T p.S997L | Missense Mutation (SNP) | VAF 63/135 reads (47%) | SIFT deleterious (0); PolyPhen benign (0.341); catalogued as COSV68024455; called by muse, mutect2, varscan2
- DSEL | c.1881G>A p.M627I | Missense Mutation (SNP) | VAF 32/64 reads (50%) | SIFT tolerated (0.34); PolyPhen benign (0.041); catalogued as COSV100025736; called by muse, mutect2, varscan2
- EAF2 | c.361C>T p.Q121* | Nonsense Mutation (SNP) | VAF 36/84 reads (43%) | catalogued as COSV99877397, COSV99877531; called by muse, mutect2, varscan2
- EHMT1 | c.760C>T p.P254S | Missense Mutation (SNP) | VAF 58/132 reads (44%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.01); catalogued as rs1216113411, COSV100603974; called by muse, mutect2, varscan2
- ELOA2 | c.1272G>A p.W424* | Nonsense Mutation (SNP) | VAF 45/119 reads (38%) | catalogued as COSV99796905; called by muse, mutect2, varscan2
- ERC2 | c.1576G>A p.E526K | Missense Mutation (SNP) | VAF 15/32 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV99885862; called by muse, mutect2, varscan2
- ERLEC1 | c.490G>A p.E164K | Missense Mutation (SNP) | VAF 38/75 reads (51%) | SIFT tolerated (0.21); PolyPhen benign (0.13); catalogued as COSV99483068; called by muse, mutect2, varscan2
- ESF1 | c.496A>T p.K166* | Nonsense Mutation (SNP) | VAF 12/33 reads (36%) | catalogued as COSV99176397; called by muse, mutect2, varscan2
- F13B | c.1312C>T p.R438C | Missense Mutation (SNP) | VAF 42/109 reads (39%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.759); catalogued as rs748341394, COSV66373444; called by muse, mutect2, varscan2
- FAM111A | c.1028C>T p.S343L | Missense Mutation (SNP) | VAF 26/75 reads (35%) | SIFT tolerated (0.39); PolyPhen benign (0); catalogued as rs748840540, COSV64655211; called by muse, mutect2, varscan2
- FAM47C | c.1999C>T p.P667S | Missense Mutation (SNP) | VAF 50/155 reads (32%) | SIFT tolerated (0.43); PolyPhen benign (0.113); catalogued as rs781969441, COSV63724434; called by muse, varscan2
- FER1L6 | c.761G>A p.G254E | Missense Mutation (SNP) | VAF 54/234 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.585); catalogued as COSV101205942, COSV67550661; called by muse, mutect2, varscan2
- FIBIN | c.398C>T p.S133L | Missense Mutation (SNP) | VAF 37/90 reads (41%) | SIFT tolerated, low confidence (0.09); PolyPhen probably damaging (0.992); catalogued as rs1213240103, COSV59412664; called by muse, mutect2, varscan2
- FLG2 | c.5173G>A p.G1725R | Missense Mutation (SNP) | VAF 151/477 reads (32%) | SIFT tolerated (0.09); PolyPhen benign (0.023); catalogued as COSV101165936, COSV66168020; called by muse, mutect2, varscan2
- FMN2 | c.1738G>A p.E580K | Missense Mutation (SNP) | VAF 73/120 reads (61%) | SIFT deleterious (0); PolyPhen benign (0.085); catalogued as COSV60422213, COSV60431213; called by muse, mutect2, varscan2
- FN1 | c.3362C>T p.P1121L | Missense Mutation (SNP) | VAF 21/64 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100117326; called by muse, mutect2, varscan2
- FNBP1L | c.734C>T p.S245L | Missense Mutation (SNP) | VAF 43/91 reads (47%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); catalogued as COSV99554647; called by muse, mutect2, varscan2
- FRY | c.7156C>T p.P2386S | Missense Mutation (SNP) | VAF 5/61 reads (8%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs1466392259, COSV100969394, COSV66571933; called by muse, mutect2
- FSCN3 | c.380C>T p.S127F | Missense Mutation (SNP) | VAF 68/128 reads (53%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV50001038; called by muse, mutect2, varscan2
- FSTL5 | c.851G>A p.R284K | Missense Mutation (SNP) | VAF 14/35 reads (40%) | SIFT deleterious (0.01); PolyPhen benign (0.078); catalogued as rs766740737, COSV100056711; called by muse, mutect2, varscan2
- GABRA4 | c.1378C>T p.R460* | Nonsense Mutation (SNP) | VAF 44/94 reads (47%) | catalogued as COSV51921778, COSV51924561; called by muse, mutect2, varscan2
- GCK | c.579+1G>A p.X193_splice | Splice Site (SNP) | VAF 109/181 reads (60%) | catalogued as CS068319, CS096983, CS096984, COSV100357252; called by muse, mutect2, varscan2
- GIMAP2 | c.374C>T p.A125V | Missense Mutation (SNP) | VAF 15/65 reads (23%) | SIFT tolerated (0.06); PolyPhen benign (0.13); catalogued as rs144149379, COSV99785389; called by muse, mutect2, varscan2
- GPR158 | c.3250G>A p.D1084N | Missense Mutation (SNP) | VAF 42/59 reads (71%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as COSV100893723; called by muse, mutect2, varscan2
- GPRIN2 | c.746C>T p.A249V | Missense Mutation (SNP) | VAF 28/86 reads (33%) | SIFT tolerated (0.31); PolyPhen benign (0.011); catalogued as COSV100966411; called by muse, mutect2, varscan2
- GRB2 | c.635C>T p.P212L | Missense Mutation (SNP) | VAF 105/296 reads (35%) | SIFT deleterious (0.04); PolyPhen benign (0.23); catalogued as COSV100353495; called by muse, mutect2, varscan2
- GRIA2 | c.1274C>T p.P425L | Missense Mutation (SNP) | VAF 13/26 reads (50%) | SIFT deleterious (0.04); PolyPhen benign (0.056); catalogued as rs1450455479, COSV99644748; called by muse, mutect2, varscan2
- GRM1 | c.127G>A p.G43R | Missense Mutation (SNP) | VAF 78/98 reads (80%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51183854; called by muse, mutect2, varscan2
- GRM8 | c.1090G>A p.E364K | Missense Mutation (SNP) | VAF 27/98 reads (28%) | SIFT deleterious (0.02); PolyPhen benign (0.369); catalogued as COSV100283641; called by muse, mutect2, varscan2
- H1-6 | c.418G>A p.D140N | Missense Mutation (SNP) | VAF 63/163 reads (39%) | SIFT tolerated (0.06); PolyPhen benign (0.003); catalogued as rs775518111, COSV100619569; called by muse, mutect2, varscan2
- HCFC2 | c.1666+1G>C p.X556_splice | Splice Site (SNP) | VAF 28/54 reads (52%) | catalogued as COSV99983136; called by muse, varscan2
- HDAC9 | c.503C>T p.S168F | Missense Mutation (SNP) | VAF 48/92 reads (52%) | SIFT tolerated (0.35); PolyPhen probably damaging (0.923); catalogued as COSV67779408; called by muse, mutect2, varscan2
- HLA-F | c.599T>C p.L200P | Missense Mutation (SNP) | VAF 19/91 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV99466078; called by muse, mutect2, varscan2
- HPN | c.1052G>A p.G351D | Missense Mutation (SNP) | VAF 68/150 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99385161; called by muse, mutect2
- HUWE1 | c.2167G>A p.E723K | Missense Mutation (SNP) | VAF 55/129 reads (43%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.755); catalogued as COSV99472771; called by muse, mutect2, varscan2
- HYDIN | c.6143-1G>A p.X2048_splice | Splice Site (SNP) | VAF 30/82 reads (37%) | catalogued as COSV99993092; called by muse, mutect2, varscan2
- IDO1 | c.323C>T p.A108V | Missense Mutation (SNP) | VAF 25/59 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV99503393; called by muse, mutect2, varscan2
- IER2 | c.475C>T p.R159C | Missense Mutation (SNP) | VAF 24/33 reads (73%) | SIFT tolerated (0.07); PolyPhen benign (0.056); catalogued as rs1230141358, COSV99460241; called by muse, mutect2, varscan2
- IGKV1-8 | c.230G>A p.G77E | Missense Mutation (SNP) | VAF 58/239 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.796); catalogued as rs757358188; called by muse, mutect2, varscan2
- IGLV4-69 | c.247C>T p.P83S | Missense Mutation (SNP) | VAF 69/143 reads (48%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.873); catalogued as rs1372071379; called by muse, mutect2, varscan2
- IL1RL2 | c.852G>A p.V284= | Splice Region (SNP) | VAF 49/98 reads (50%) | catalogued as rs536334733, COSV51817579; called by muse, mutect2, varscan2
- ITPR3 | c.5254G>A p.E1752K | Missense Mutation (SNP) | VAF 54/190 reads (28%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.577); catalogued as COSV100967506; called by muse, mutect2, varscan2
- KCTD10 | c.901C>T p.H301Y | Missense Mutation (SNP) | VAF 43/93 reads (46%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.968); catalogued as COSV99949309; called by muse, mutect2, varscan2
- KHDC3L | c.619C>T p.R207C | Missense Mutation (SNP) | VAF 36/74 reads (49%) | SIFT tolerated (0.07); PolyPhen benign (0.188); catalogued as rs866082650, COSV64859035; called by muse, mutect2, varscan2
- KIAA1217 | c.3337C>T p.P1113S | Missense Mutation (SNP) | VAF 28/38 reads (74%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs907124761, COSV100286749; called by muse, mutect2, varscan2
- KIF4A | c.262G>A p.G88R | Missense Mutation (SNP) | VAF 45/87 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100979551; called by muse, mutect2, varscan2
- KIR2DL4 | c.359G>A p.S120N (on ENST00000396284; = p.S81N on NM_001080770.2) | Missense Mutation (SNP) | VAF 45/110 reads (41%) | SIFT tolerated (1); PolyPhen benign (0.011); catalogued as rs1463597984; called by muse, mutect2, varscan2
- KLHL15 | c.8G>A p.G3E | Missense Mutation (SNP) | VAF 8/27 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.366); catalogued as COSV100044223; called by muse, mutect2, varscan2
- KLK2 | c.250G>A p.E84K | Missense Mutation (SNP) | VAF 24/59 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.949); catalogued as COSV100319977; called by muse, mutect2, varscan2
- LAD1 | c.671G>A p.R224K | Missense Mutation (SNP) | VAF 79/179 reads (44%) | SIFT tolerated (0.5); PolyPhen benign (0.007); catalogued as COSV100943872; called by muse, mutect2, varscan2
- LAMA3 | c.3425C>G p.P1142R | Missense Mutation (SNP) | VAF 34/69 reads (49%) | SIFT deleterious (0.01); PolyPhen benign (0.093); catalogued as COSV100557019; called by muse, mutect2, varscan2
- LCLAT1 | c.40C>T p.P14S | Missense Mutation (SNP) | VAF 39/235 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.026); catalogued as COSV100092724; called by muse, mutect2, varscan2
- LCT | c.1660G>A p.G554S | Missense Mutation (SNP) | VAF 17/77 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as rs994457775, COSV99929684; called by muse, mutect2, varscan2
- LETM1 | c.1391C>T p.A464V | Missense Mutation (SNP) | VAF 66/159 reads (42%) | SIFT tolerated (0.31); PolyPhen benign (0.03); catalogued as COSV57105648; called by muse, mutect2, varscan2
- LIMCH1 | c.3224G>A p.R1075K | Missense Mutation (SNP) | VAF 29/65 reads (45%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.982); catalogued as COSV58280205; called by muse, mutect2, varscan2
- LRP1B | c.1379G>A p.R460Q | Missense Mutation (SNP) | VAF 9/46 reads (20%) | SIFT tolerated (0.15); PolyPhen benign (0.115); catalogued as rs1172668136, COSV67200351; called by muse, mutect2, varscan2
- LRRC4B | c.748C>T p.Q250* | Nonsense Mutation (SNP) | VAF 24/62 reads (39%) | catalogued as COSV100975949; called by muse, mutect2, varscan2
- LTK | c.1063C>T p.P355S | Missense Mutation (SNP) | VAF 46/108 reads (43%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as COSV99779063; called by muse, mutect2, varscan2
- MAGEC3 | c.1192G>A p.G398S | Missense Mutation (SNP) | VAF 9/12 reads (75%) | SIFT tolerated (0.11); PolyPhen benign (0.235); catalogued as rs1164415467, COSV68924339; called by muse, mutect2, varscan2
- MAPK4 | c.1718C>T p.P573L | Missense Mutation (SNP) | VAF 19/42 reads (45%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as COSV101245572, COSV68544415; called by muse, mutect2, varscan2
- MARVELD3 | c.715C>T p.Q239* | Nonsense Mutation (SNP) | VAF 84/218 reads (39%) | catalogued as COSV99194837; called by muse, mutect2, varscan2
- MATN4 | c.1615G>A p.E539K (on ENST00000372754; = p.E498K on NM_003833.4) | Missense Mutation (SNP) | VAF 25/87 reads (29%) | PolyPhen benign (0.042); catalogued as COSV100637062; called by muse, mutect2, varscan2
- MED12 | c.2894C>T p.S965F | Missense Mutation (SNP) | VAF 16/46 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV100378393; called by muse, mutect2, varscan2
- MFSD2A | c.1174A>T p.S392C (on ENST00000372809 / NM_001136493.3; = p.S379C on NM_032793.5 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 37/87 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); catalogued as COSV100861697; called by muse, mutect2, varscan2
- MLF2 | c.602C>T p.S201F | Missense Mutation (SNP) | VAF 12/24 reads (50%) | SIFT tolerated (0.19); PolyPhen benign (0.201); catalogued as rs1052291262, COSV99180093; called by muse, mutect2, varscan2
- MLLT6 | c.1129C>T p.P377S | Missense Mutation (SNP) | VAF 21/49 reads (43%) | SIFT tolerated (0.87); PolyPhen benign (0.242); catalogued as rs1317598745; called by muse, mutect2, varscan2
- MLXIPL | c.2310+1G>A p.X770_splice | Splice Site (SNP) | VAF 93/145 reads (64%) | catalogued as COSV100515394; called by muse, mutect2, varscan2
- MMP17 | c.1408C>T p.P470S | Missense Mutation (SNP) | VAF 32/81 reads (40%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as COSV100861944; called by muse, mutect2, varscan2
- MMP28 | c.1273C>T p.P425S | Missense Mutation (SNP) | VAF 7/16 reads (44%) | SIFT tolerated (0.43); PolyPhen benign (0.23); catalogued as rs1555603491; called by muse, mutect2, varscan2
- MTFMT | c.271C>T p.P91S | Missense Mutation (SNP) | VAF 22/57 reads (39%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.952); catalogued as rs765973652, COSV99584382; called by muse, mutect2, varscan2
- MUC16 | c.26673G>A p.M8891I | Missense Mutation (SNP) | VAF 61/87 reads (70%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.001); catalogued as COSV67464673; called by muse, mutect2, varscan2
- MUC16 | c.13096T>A p.F4366I | Missense Mutation (SNP) | VAF 35/47 reads (74%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.105); catalogued as COSV101200176; called by muse, mutect2, varscan2
- MUC17 | c.12808G>A p.E4270K | Missense Mutation (SNP) | VAF 36/102 reads (35%) | SIFT tolerated (0.63); PolyPhen benign (0.039); catalogued as rs200201977; called by muse, mutect2, varscan2
- MUC4 | c.12803C>T p.P4268L (on ENST00000463781 / NM_018406.7; = p.P32L on NM_004532.6) | Missense Mutation (SNP) | VAF 19/61 reads (31%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.003); catalogued as rs142178516, COSV100203565; called by muse, mutect2, varscan2
- MYH15 | c.5179C>T p.L1727F | Missense Mutation (SNP) | VAF 87/196 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99842945, COSV99843476; called by muse, mutect2, varscan2
- MYH2 | c.2602G>A p.E868K | Missense Mutation (SNP) | VAF 32/93 reads (34%) | SIFT tolerated (0.38); PolyPhen benign (0.052); catalogued as rs267604724, COSV55432215; called by muse, mutect2, varscan2
- NCKAP5 | c.1490G>A p.R497K | Missense Mutation (SNP) | VAF 50/94 reads (53%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.895); catalogued as COSV100492607; called by muse, mutect2, varscan2
- NEB | c.9412G>A p.D3138N | Missense Mutation (SNP) | VAF 41/162 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as rs374760449; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- NELL2 | c.2003G>A p.G668E | Missense Mutation (SNP) | VAF 20/43 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100421310, COSV61580273; called by muse, mutect2, varscan2
- NEO1 | c.2690C>T p.T897I | Missense Mutation (SNP) | VAF 29/78 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV99982247; called by muse, mutect2, varscan2
- NFATC1 | c.838C>T p.H280Y | Missense Mutation (SNP) | VAF 37/71 reads (52%) | SIFT deleterious (0.01); PolyPhen benign (0.316); catalogued as rs1463826942, COSV99501859; called by muse, mutect2, varscan2
- NLRC4 | c.640G>A p.E214K | Missense Mutation (SNP) | VAF 38/71 reads (54%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as rs1461102635, COSV100707418; called by muse, mutect2, varscan2
- NOS1 | c.4043G>A p.G1348E | Missense Mutation (SNP) | VAF 53/203 reads (26%) | SIFT tolerated (0.29); PolyPhen benign (0.351); catalogued as rs781077618, COSV57609674; called by muse, mutect2, varscan2
- NOS1 | c.4042G>A p.G1348R | Missense Mutation (SNP) | VAF 54/205 reads (26%) | SIFT tolerated (0.24); PolyPhen benign (0.026); catalogued as rs1370120249, COSV100500793; called by muse, mutect2, varscan2
- NPAP1 | c.284G>A p.R95K | Missense Mutation (SNP) | VAF 22/47 reads (47%) | SIFT tolerated (1); PolyPhen benign (0.067); catalogued as COSV61504498; called by muse, mutect2, varscan2
- NRXN1 | c.2986G>A p.D996N | Missense Mutation (SNP) | VAF 7/31 reads (23%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as COSV100455497; called by muse, mutect2, varscan2
- NTRK1 | c.911C>T p.S304F | Missense Mutation (SNP) | VAF 13/29 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.892); catalogued as COSV62323915, COSV62324615; called by muse, mutect2, varscan2
- NUGGC | c.178G>A p.V60I | Missense Mutation (SNP) | VAF 30/58 reads (52%) | SIFT tolerated (0.3); PolyPhen benign (0.069); catalogued as rs1328366867, COSV100429357; called by muse, mutect2, varscan2
- NUP205 | c.4417T>C p.Y1473H | Missense Mutation (SNP) | VAF 97/154 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99607123; called by muse, mutect2, varscan2
- ODF1 | c.214C>T p.P72S | Missense Mutation (SNP) | VAF 92/155 reads (59%) | SIFT tolerated, low confidence (0.1); PolyPhen probably damaging (0.992); catalogued as COSV99574250; called by muse, mutect2, varscan2
- OR1N2 | c.611C>T p.T204I | Missense Mutation (SNP) | VAF 104/258 reads (40%) | SIFT tolerated (0.68); PolyPhen benign (0.007); catalogued as rs1274397670, COSV101031408; called by muse, mutect2, varscan2
- OR2G3 | c.886G>A p.D296N | Missense Mutation (SNP) | VAF 46/114 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.776); catalogued as rs1028980569, COSV60682224; called by muse, mutect2
- OR2J2 | c.325G>A p.G109R | Missense Mutation (SNP) | VAF 130/408 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as rs780124835, COSV101013389; called by muse, mutect2, varscan2
- OR4D5 | c.16C>T p.H6Y | Missense Mutation (SNP) | VAF 54/133 reads (41%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV100189791, COSV100190016; called by muse, mutect2, varscan2
- OR4M1 | c.499C>T p.P167S | Missense Mutation (SNP) | VAF 104/242 reads (43%) | SIFT deleterious (0.01); PolyPhen benign (0.078); catalogued as COSV60059274; called by muse, mutect2, varscan2
- OR51G2 | c.671C>T p.A224V | Missense Mutation (SNP) | VAF 18/58 reads (31%) | SIFT tolerated (1); PolyPhen benign (0.02); catalogued as rs200691528, COSV100432120; called by muse, mutect2, varscan2
- ORAI2 | c.5G>A p.S2N | Missense Mutation (SNP) | VAF 179/323 reads (55%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.528); catalogued as rs1217516417, COSV100709938; called by muse, mutect2, varscan2
- OSBPL3 | c.1622C>T p.S541F | Missense Mutation (SNP) | VAF 94/174 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100514225; called by muse, mutect2, varscan2
- OTOA | c.2000C>T p.S667F (on ENST00000286149; = p.S653F on NM_144672.4) | Missense Mutation (SNP) | VAF 72/147 reads (49%) | SIFT tolerated (0.7); PolyPhen benign (0.228); catalogued as COSV53752818, COSV99624842; called by muse, mutect2, varscan2
- P3H3 | c.934C>T p.P312S | Missense Mutation (SNP) | VAF 7/33 reads (21%) | SIFT deleterious (0.03); PolyPhen benign (0.006); catalogued as COSV99301337; called by muse, mutect2, varscan2
- PARD3B | c.1525C>T p.L509F | Missense Mutation (SNP) | VAF 52/95 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100593836; called by muse, mutect2, varscan2
- PARM1 | c.821T>C p.F274S | Missense Mutation (SNP) | VAF 6/15 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100268168; called by muse, mutect2, varscan2
- PARP14 | c.793C>T p.P265S | Missense Mutation (SNP) | VAF 13/33 reads (39%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.898); catalogued as rs914724263, COSV71734838; called by muse, mutect2, varscan2
- PCDHB10 | c.574C>T p.P192S | Missense Mutation (SNP) | VAF 122/158 reads (77%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV53384168; called by muse, varscan2
- PCDHGA2 | c.2390T>C p.L797P | Missense Mutation (SNP) | VAF 44/55 reads (80%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.019); catalogued as rs369665414; called by muse, mutect2, varscan2
- PCNX1 | c.6896G>A p.R2299Q | Missense Mutation (SNP) | VAF 36/84 reads (43%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.493); catalogued as rs763292801, COSV53091279; called by muse, mutect2, varscan2
- PCNX4 | c.1853C>T p.A618V (on ENST00000406854 / NM_001330177.2; = p.A384V on NM_022495.5) | Missense Mutation (SNP) | VAF 17/41 reads (41%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.875); catalogued as COSV100470449; called by muse, mutect2, varscan2
- PDGFRA | c.215G>A p.R72K | Missense Mutation (SNP) | VAF 73/184 reads (40%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as COSV99956805; called by muse, mutect2, varscan2
- PHACTR3 | c.853C>T p.H285Y | Missense Mutation (SNP) | VAF 39/99 reads (39%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.946); catalogued as COSV100732725; called by muse, mutect2, varscan2
- PHKB | c.2633G>A p.W878* | Nonsense Mutation (SNP) | VAF 51/111 reads (46%) | catalogued as rs1000274245, COSV100067489; called by muse, mutect2, varscan2
- PLA2G4D | c.1526G>A p.G509E | Missense Mutation (SNP) | VAF 64/130 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1447897877, COSV99299766; called by muse, mutect2, varscan2
- POTEF | c.3220T>C p.C1074R | Missense Mutation (SNP) | VAF 33/213 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV100664998; called by muse, mutect2, varscan2
- PPFIA2 | c.2627G>A p.R876Q | Missense Mutation (SNP) | VAF 9/29 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.647); catalogued as COSV100333978; called by muse, mutect2, varscan2
- PRAMEF12 | c.338G>A p.W113* | Nonsense Mutation (SNP) | VAF 128/332 reads (39%) | catalogued as COSV100743339; called by muse, mutect2, varscan2
- PRDM2 | c.3091C>T p.P1031S | Missense Mutation (SNP) | VAF 47/113 reads (42%) | SIFT deleterious (0.01); PolyPhen benign (0.194); catalogued as COSV99341891; called by muse, mutect2, varscan2
- PREX2 | c.159G>A p.M53I | Missense Mutation (SNP) | VAF 12/25 reads (48%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV55796137, COSV99907893; called by muse, mutect2, varscan2
- PRICKLE1 | c.1436G>A p.G479E | Missense Mutation (SNP) | VAF 24/55 reads (44%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.901); catalogued as COSV100453935; called by muse, mutect2, varscan2
- PRX | c.4055C>T p.P1352L | Missense Mutation (SNP) | VAF 10/33 reads (30%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as COSV52519974, COSV99396761; called by muse, mutect2, varscan2
- PSD | c.679G>A p.E227K | Missense Mutation (SNP) | VAF 14/20 reads (70%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.344); catalogued as COSV99192867; called by muse, mutect2, varscan2
- PSG6 | c.1075C>T p.P359S | Missense Mutation (SNP) | VAF 162/358 reads (45%) | SIFT tolerated (0.08); PolyPhen probably damaging (1); catalogued as COSV51830876; called by muse, mutect2, varscan2
- PTCHD1 | c.1871C>T p.S624L | Missense Mutation (SNP) | VAF 50/110 reads (45%) | SIFT tolerated (0.3); PolyPhen benign (0.015); catalogued as rs375988064, COSV65058676; called by muse, mutect2, varscan2
- PTPRB | c.5194C>T p.R1732* | Nonsense Mutation (SNP) | VAF 8/15 reads (53%) | catalogued as rs724159879, COSV54246215; called by muse, mutect2, varscan2
- PTPRC | c.131C>T p.P44L | Missense Mutation (SNP) | VAF 84/166 reads (51%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV100722758; called by muse, mutect2, varscan2
- PTPRT | c.3503C>T p.P1168L | Missense Mutation (SNP) | VAF 75/169 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV100628077; called by muse, mutect2, varscan2
- RECK | c.1477C>T p.P493S | Missense Mutation (SNP) | VAF 23/47 reads (49%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV100937522; called by muse, mutect2, varscan2
- RIC8B | c.947C>G p.P316R | Missense Mutation (SNP) | VAF 29/70 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.823); catalogued as COSV100822628; called by muse, mutect2, varscan2
- RIT2 | c.277G>A p.E93K | Missense Mutation (SNP) | VAF 146/373 reads (39%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.996); catalogued as COSV99950399; called by muse, mutect2, varscan2
- RLF | c.115C>T p.P39S | Missense Mutation (SNP) | VAF 16/43 reads (37%) | SIFT tolerated, low confidence (0.33); PolyPhen possibly damaging (0.61); catalogued as COSV101035463; called by muse, mutect2, varscan2
- RNF123 | c.3023C>T p.S1008F | Missense Mutation (SNP) | VAF 15/48 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV100246637; called by muse, mutect2, varscan2
- ROR2 | c.1820C>T p.S607F | Missense Mutation (SNP) | VAF 36/74 reads (49%) | SIFT deleterious (0); PolyPhen possibly damaging (0.872); catalogued as rs769849104, COSV65224475; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- RPS6 | c.64C>T p.R22C | Missense Mutation (SNP) | VAF 35/97 reads (36%) | SIFT tolerated (0.27); PolyPhen benign (0.035); catalogued as COSV100194531; called by muse, mutect2, varscan2
- RPS6 | c.63A>T p.E21D | Missense Mutation (SNP) | VAF 37/101 reads (37%) | SIFT tolerated (0.2); PolyPhen benign (0.031); catalogued as rs1173102789, COSV100194533; called by muse, mutect2, varscan2
- RPS6KC1 | c.2908C>T p.P970S | Missense Mutation (SNP) | VAF 3/25 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV100873927; called by muse, mutect2
- RSPH10B2 | c.160G>A p.E54K | Missense Mutation (SNP) | VAF 78/251 reads (31%) | SIFT tolerated (0.05); PolyPhen benign (0.058); catalogued as rs746889216, COSV51870264; called by muse, mutect2, varscan2
- SAGE1 | c.775G>A p.E259K | Missense Mutation (SNP) | VAF 67/150 reads (45%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.474); catalogued as COSV100187472; called by muse, mutect2, varscan2
- SALL1 | c.3758C>T p.S1253F | Missense Mutation (SNP) | VAF 25/67 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99174604; called by muse, mutect2, varscan2
- SBF1 | c.3829C>T p.P1277S | Missense Mutation (SNP) | VAF 9/17 reads (53%) | SIFT tolerated (0.86); PolyPhen benign (0.086); catalogued as COSV100817824; called by muse, mutect2, varscan2
- SCN10A | c.5777G>A p.R1926K | Missense Mutation (SNP) | VAF 80/176 reads (45%) | SIFT tolerated (0.76); PolyPhen possibly damaging (0.629); catalogued as rs756396678, COSV101479428; called by muse, mutect2, varscan2
- SCRT2 | c.325G>A p.D109N | Missense Mutation (SNP) | VAF 15/23 reads (65%) | SIFT deleterious (0.03); PolyPhen benign (0.019); catalogued as COSV99857183; called by muse, mutect2, varscan2
- SECISBP2L | c.374C>T p.P125L | Missense Mutation (SNP) | VAF 69/153 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55932965; called by muse, mutect2, varscan2
- SEL1L3 | c.2313G>A p.W771* | Nonsense Mutation (SNP) | VAF 37/80 reads (46%) | catalogued as COSV99340485; called by muse, mutect2, varscan2
- SELP | c.1175C>T p.P392L | Missense Mutation (SNP) | VAF 30/79 reads (38%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as COSV99740201; called by muse, mutect2, varscan2
- SERPINA4 | c.99C>A p.N33K | Missense Mutation (SNP) | VAF 39/95 reads (41%) | SIFT tolerated (0.17); PolyPhen benign (0.01); catalogued as COSV100097236; called by muse, mutect2, varscan2
- SEZ6L2 | c.676G>A p.E226K (on ENST00000308713 / NM_001114099.3; = p.E156K on NM_012410.4) | Missense Mutation (SNP) | VAF 37/91 reads (41%) | SIFT tolerated (0.1); PolyPhen benign (0.137); catalogued as COSV100435538; called by muse, mutect2, varscan2
- SIGLEC7 | c.782G>A p.S261N | Missense Mutation (SNP) | VAF 68/183 reads (37%) | SIFT deleterious (0.01); PolyPhen benign (0.348); catalogued as rs1432749533, COSV99978766; called by muse, mutect2, varscan2
- SLC12A3 | c.2399G>A p.G800E | Missense Mutation (SNP) | VAF 86/230 reads (37%) | SIFT tolerated (0.32); PolyPhen benign (0.013); catalogued as COSV99344330; called by muse, mutect2, varscan2
- SLC14A2 | c.625C>T p.P209S | Missense Mutation (SNP) | VAF 56/164 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99675630; called by muse, mutect2, varscan2
- SLC27A6 | c.1586T>C p.I529T | Missense Mutation (SNP) | VAF 10/14 reads (71%) | SIFT tolerated (0.6); PolyPhen benign (0.003); catalogued as COSV99322968; called by muse, mutect2, varscan2
- SLC2A14 | c.826G>A p.E276K | Missense Mutation (SNP) | VAF 25/75 reads (33%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.771); catalogued as COSV100533848; called by muse, mutect2, varscan2
- SLC2A3 | c.754G>A p.E252K | Missense Mutation (SNP) | VAF 13/72 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.973); catalogued as COSV99306716; called by muse, mutect2, varscan2
- SLC44A5 | c.1489C>T p.P497S | Missense Mutation (SNP) | VAF 105/232 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs779596124, COSV100902165; called by muse, mutect2, varscan2
- SLC5A12 | c.734G>A p.G245E | Missense Mutation (SNP) | VAF 71/161 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99745060; called by muse, mutect2, varscan2
- SLC6A3 | c.694G>A p.D232N | Missense Mutation (SNP) | VAF 47/132 reads (36%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.595); catalogued as rs764108791, COSV54366755, COSV99548491; called by muse, mutect2, varscan2
- SLCO4C1 | c.856G>A p.G286R | Missense Mutation (SNP) | VAF 61/72 reads (85%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs573882552, COSV100195174; called by muse, mutect2, varscan2
- SLCO5A1 | c.2174C>T p.S725F | Missense Mutation (SNP) | VAF 51/214 reads (24%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.989); catalogued as COSV99480244; called by muse, mutect2, varscan2
- SPHKAP | c.4690C>T p.Q1564* | Nonsense Mutation (SNP) | VAF 10/21 reads (48%) | catalogued as COSV100764210; called by muse, mutect2, varscan2
- SPINT2 | c.231T>A p.N77K | Missense Mutation (SNP) | VAF 54/108 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100007570; called by muse, mutect2, varscan2
- SPOCK3 | c.844G>A p.E282K | Missense Mutation (SNP) | VAF 43/91 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV62724339, COSV62726621; called by muse, mutect2, varscan2
- SPTB | c.6143T>G p.I2048S | Missense Mutation (SNP) | VAF 57/137 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.786); catalogued as COSV100731144; called by muse, mutect2, varscan2
- SRSF12 | c.409C>T p.L137F | Missense Mutation (SNP) | VAF 7/24 reads (29%) | SIFT tolerated (0.61); PolyPhen benign (0.003); catalogued as rs773964959, COSV101504979; called by muse, mutect2, varscan2
- SSH2 | c.2686C>T p.R896C | Missense Mutation (SNP) | VAF 170/400 reads (43%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as rs763639780, COSV52173664; called by muse, mutect2, varscan2
- STPG1 | c.745C>T p.P249S (on ENST00000337248 / NM_001199013.2; = p.P202S on NM_178122.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 30/57 reads (53%) | SIFT tolerated (0.39); PolyPhen benign (0.015); catalogued as COSV50217839; called by muse, mutect2, varscan2
- SUSD4 | c.258A>C p.Q86H | Missense Mutation (SNP) | VAF 87/178 reads (49%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.961); catalogued as COSV100663791; called by muse, mutect2, varscan2
- SYCP2L | c.1119G>A p.M373I | Missense Mutation (SNP) | VAF 20/73 reads (27%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV51650520; called by muse, mutect2, varscan2
- TAF1L | c.4112C>T p.P1371L | Missense Mutation (SNP) | VAF 101/234 reads (43%) | SIFT tolerated (0.24); PolyPhen benign (0.017); catalogued as COSV99644849; called by muse, mutect2, varscan2
- TAS2R60 | c.451C>T p.L151F | Missense Mutation (SNP) | VAF 154/251 reads (61%) | SIFT tolerated (0.52); PolyPhen benign (0.017); catalogued as COSV60332244; called by muse, mutect2, varscan2
- TBC1D10C | c.62C>T p.S21F | Missense Mutation (SNP) | VAF 24/52 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1037112343, COSV100408258; called by muse, mutect2, varscan2
- TBC1D7 | c.328C>T p.R110C | Missense Mutation (SNP) | VAF 108/363 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.974); catalogued as rs746378127, COSV58243753, COSV58244831; called by muse, mutect2, varscan2
- TCAIM | c.1028C>T p.S343F | Missense Mutation (SNP) | VAF 23/71 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.568); catalogued as rs201334117, COSV100703293; called by muse, mutect2, varscan2
- TCTE1 | c.453G>A p.W151* | Nonsense Mutation (SNP) | VAF 43/99 reads (43%) | catalogued as COSV65255120; called by muse, mutect2, varscan2
- TEAD1 | c.307C>T p.R103C | Missense Mutation (SNP) | VAF 54/163 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as COSV57561501; called by muse, mutect2, varscan2
- TEAD4 | c.55C>T p.P19S | Missense Mutation (SNP) | VAF 45/138 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.282); catalogued as rs1239272473, COSV100622070; called by muse, mutect2, varscan2
- TEAD4 | c.56C>T p.P19L | Missense Mutation (SNP) | VAF 46/143 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.355); catalogued as COSV100622072; called by muse, mutect2, varscan2
- TEF | c.199G>A p.A67T | Missense Mutation (SNP) | VAF 74/153 reads (48%) | SIFT tolerated (0.27); PolyPhen benign (0.005); catalogued as rs749723725, COSV56747913; called by muse, mutect2, varscan2
- TENM4 | c.3158C>T p.S1053F | Missense Mutation (SNP) | VAF 61/126 reads (48%) | SIFT deleterious (0.04); PolyPhen benign (0.135); catalogued as COSV99575584; called by muse, mutect2, varscan2
- TENT4A | c.2207C>T p.S736F | Missense Mutation (SNP) | VAF 24/50 reads (48%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.935); catalogued as COSV100049047, COSV100049219; called by muse, mutect2, varscan2
- TENT5D | c.922G>A p.E308K | Missense Mutation (SNP) | VAF 52/128 reads (41%) | SIFT tolerated (0.05); PolyPhen benign (0.043); catalogued as COSV100382789; called by muse, mutect2, varscan2
- TET3 | c.2261C>T p.P754L | Missense Mutation (SNP) | VAF 6/15 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.496); catalogued as COSV99996390; called by muse, mutect2, varscan2
- TEX14 | c.4247C>T p.P1416L (on ENST00000240361 / NM_001201457.2; = p.P1370L on NM_031272.5) | Missense Mutation (SNP) | VAF 80/182 reads (44%) | SIFT tolerated (0.11); PolyPhen benign (0.003); catalogued as COSV53613269; called by muse, mutect2, varscan2
- TG | c.7993T>C p.S2665P | Missense Mutation (SNP) | VAF 25/104 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV99601405; called by muse, mutect2, varscan2
- TIE1 | c.217C>T p.P73S | Missense Mutation (SNP) | VAF 11/28 reads (39%) | SIFT tolerated (0.9); PolyPhen benign (0); catalogued as COSV100992097; called by muse, mutect2, varscan2
- TLL2 | c.593G>A p.R198K | Missense Mutation (SNP) | VAF 43/53 reads (81%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as COSV100780333, COSV104417649; called by muse, mutect2, varscan2
- TMC8 | c.1975C>T p.P659S | Missense Mutation (SNP) | VAF 10/22 reads (45%) | SIFT tolerated (0.64); PolyPhen benign (0.031); catalogued as COSV100573756; called by muse, mutect2, varscan2
- TMEM223 | c.31G>C p.G11R | Missense Mutation (SNP) | VAF 10/18 reads (56%) | SIFT tolerated, low confidence (0.71); PolyPhen benign (0); catalogued as COSV99585253; called by muse, mutect2, varscan2
- TMEM38B | c.56C>T p.P19L | Missense Mutation (SNP) | VAF 52/99 reads (53%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); catalogued as COSV101020049; called by muse, mutect2, varscan2
- TRANK1 | c.8722G>A p.G2908S | Missense Mutation (SNP) | VAF 9/20 reads (45%) | SIFT tolerated (0.2); PolyPhen benign (0.202); catalogued as COSV100083333; called by muse, mutect2, varscan2
- TRANK1 | c.2302G>A p.D768N | Missense Mutation (SNP) | VAF 140/369 reads (38%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as COSV100083338; called by muse, mutect2, varscan2
- TRIM69 | c.319C>T p.P107S | Missense Mutation (SNP) | VAF 50/106 reads (47%) | SIFT tolerated (0.51); PolyPhen benign (0.054); catalogued as COSV57805105; called by muse, mutect2, varscan2
- TRIO | c.5197C>T p.H1733Y | Missense Mutation (SNP) | VAF 23/87 reads (26%) | SIFT tolerated (1); PolyPhen probably damaging (0.954); catalogued as rs368342075, COSV60095951; called by muse, mutect2, varscan2
- TSPAN31 | c.172C>T p.L58F | Missense Mutation (SNP) | VAF 58/98 reads (59%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.913); catalogued as rs1163221424, COSV99223469; called by muse, mutect2, varscan2
- TTC3 | c.3367C>T p.P1123S | Missense Mutation (SNP) | VAF 95/201 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1390644418, COSV100695655; called by muse, mutect2, varscan2
- TTN | c.99001C>T p.P33001S (on ENST00000591111; = p.P25577S on NM_003319.4) | Missense Mutation (SNP) | VAF 16/51 reads (31%) | PolyPhen probably damaging (0.975); catalogued as COSV100617484; called by muse, mutect2, varscan2
- TTN | c.57094G>A p.E19032K (on ENST00000591111; = p.E11608K on NM_003319.4) | Missense Mutation (SNP) | VAF 105/186 reads (56%) | PolyPhen probably damaging (0.994); catalogued as COSV100617490; called by muse, mutect2, varscan2
- TTN | c.39445G>A p.E13149K (on ENST00000591111; = p.E5725K on NM_003319.4) | Missense Mutation (SNP) | VAF 19/28 reads (68%) | PolyPhen probably damaging (0.994); catalogued as rs762712953, COSV59960130; called by muse, mutect2, varscan2
- TTN | c.29644G>A p.E9882K (on ENST00000591111; = p.E8955K on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 10/57 reads (18%) | PolyPhen probably damaging (0.969); catalogued as COSV60325180; called by muse, mutect2, varscan2
- TULP1 | c.757G>A p.E253K | Missense Mutation (SNP) | VAF 229/668 reads (34%) | SIFT tolerated (0.1); PolyPhen benign (0.005); catalogued as COSV100004229; called by muse, mutect2, varscan2
- TUT4 | c.304C>T p.P102S | Missense Mutation (SNP) | VAF 56/141 reads (40%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.051); catalogued as COSV99932465; called by muse, mutect2
- UBXN11 | c.161C>T p.S54F | Missense Mutation (SNP) | VAF 64/166 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.548); catalogued as rs963268878, COSV59025907; called by muse, mutect2, varscan2
- USF1 | c.254C>T p.P85L | Missense Mutation (SNP) | VAF 43/95 reads (45%) | SIFT deleterious (0.01); PolyPhen benign (0.065); catalogued as COSV57035505, COSV99231084; called by muse, mutect2, varscan2
- USH2A | c.13801C>T p.P4601S | Missense Mutation (SNP) | VAF 113/204 reads (55%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs779202230, COSV100236747; called by muse, mutect2, varscan2
- USH2A | c.9052G>A p.G3018R | Missense Mutation (SNP) | VAF 17/47 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.87); catalogued as COSV100236750; called by muse, mutect2, varscan2
- USH2A | c.6367T>G p.C2123G | Missense Mutation (SNP) | VAF 40/104 reads (38%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV100236752; called by muse, mutect2, varscan2
- USP50 | c.662C>T p.P221L (on ENST00000616326; = p.P212L on NM_203494.5) | Missense Mutation (SNP) | VAF 20/47 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as rs1040615668, COSV101597727; called by muse, mutect2, varscan2
- USP7 | c.251C>T p.S84L | Missense Mutation (SNP) | VAF 32/91 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.596); catalogued as COSV100784219, COSV100784311; called by muse, mutect2, varscan2
- VPS16 | c.1423C>T p.L475F | Missense Mutation (SNP) | VAF 57/109 reads (52%) | SIFT tolerated (0.06); PolyPhen benign (0.023); catalogued as COSV100988508; called by muse, mutect2, varscan2
- VPS54 | c.2491C>T p.R831* | Nonsense Mutation (SNP) | VAF 21/83 reads (25%) | catalogued as rs770650729, COSV99708235; called by muse, mutect2, varscan2
- WASF3 | c.322G>C p.D108H | Missense Mutation (SNP) | VAF 10/88 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV100097799, COSV100098817; called by muse, mutect2, varscan2
- WDFY3 | c.3944C>T p.S1315L | Missense Mutation (SNP) | VAF 29/60 reads (48%) | SIFT tolerated (0.13); PolyPhen benign (0.015); catalogued as rs765992636, COSV99883914; called by muse, mutect2, varscan2
- WNT5B | c.515C>T p.A172V | Missense Mutation (SNP) | VAF 12/42 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.791); catalogued as COSV100148717; called by muse, mutect2, varscan2
- ZKSCAN2 | c.2788C>T p.L930F | Missense Mutation (SNP) | VAF 37/96 reads (39%) | SIFT deleterious (0.02); PolyPhen benign (0.209); catalogued as COSV100048273; called by muse, mutect2, varscan2
- ZMYND15 | c.1171G>A p.E391K | Missense Mutation (SNP) | VAF 94/128 reads (73%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.987); catalogued as COSV99351414; called by muse, mutect2, varscan2
- ZNF253 | c.1168C>T p.H390Y | Missense Mutation (SNP) | VAF 32/38 reads (84%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV63037191; called by muse, mutect2, varscan2
- ZNF311 | c.379C>T p.P127S | Missense Mutation (SNP) | VAF 31/140 reads (22%) | SIFT tolerated (0.75); PolyPhen benign (0.018); catalogued as COSV101014158; called by muse, mutect2, varscan2
- ZNF383 | c.1010C>T p.P337L | Missense Mutation (SNP) | VAF 65/161 reads (40%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.884); catalogued as COSV61939479; called by muse, mutect2, varscan2
- ZNF480 | c.485C>T p.S162F | Missense Mutation (SNP) | VAF 32/82 reads (39%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.996); catalogued as COSV100574240; called by muse, mutect2, varscan2
- ZNF578 | c.902C>T p.S301F | Missense Mutation (SNP) | VAF 60/136 reads (44%) | SIFT tolerated (0.58); PolyPhen possibly damaging (0.628); catalogued as COSV69737349; called by muse, mutect2, varscan2
- ZSCAN31 | c.13G>A p.E5K | Missense Mutation (SNP) | VAF 38/144 reads (26%) | SIFT tolerated (0.23); PolyPhen benign (0.018); catalogued as COSV60181755, COSV60181781; called by muse, mutect2, varscan2
- HMCN1 | c.6152_6162del p.P2051Lfs*3 | Frame Shift Del (DEL) | VAF 28/69 reads (41%) | called by mutect2, pindel, varscan2
- IGHA1 | c.335C>T p.P112L | Missense Mutation (SNP) | VAF 4/13 reads (31%) | SIFT tolerated (0.28); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- IGLV3-22 | c.254C>T p.S85L | Missense Mutation (SNP) | VAF 32/82 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.965); called by muse, mutect2, varscan2
- MAGEB6B | c.979G>T p.D327Y | Missense Mutation (SNP) | VAF 123/368 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); called by muse, mutect2, varscan2
- NCBP1 | c.838_844delinsG p.S280_Y282delinsD | In Frame Del (DEL) | VAF 31/64 reads (48%) | called by pindel, varscan2*
- PRAMEF18 | c.323T>C p.V108A | Missense Mutation (SNP) | VAF 44/259 reads (17%) | SIFT tolerated (0.49); PolyPhen possibly damaging (0.874); called by muse, mutect2, varscan2
- PRAMEF19 | c.323T>C p.V108A | Missense Mutation (SNP) | VAF 128/1133 reads (11%) | SIFT tolerated (0.52); PolyPhen possibly damaging (0.869); called by muse, mutect2, varscan2
- PRAMEF5 | c.625G>A p.E209K | Missense Mutation (SNP) | VAF 34/215 reads (16%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TRBV3-1 | c.71C>T p.S24F | Missense Mutation (SNP) | VAF 41/89 reads (46%) | SIFT tolerated (0.12); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- AC109583.1 | c.906G>A p.R302= | Silent (SNP) | VAF 81/168 reads (48%) | catalogued as COSV100167911; called by muse, mutect2, varscan2
- ADAD1 | c.636C>T p.I212= | Silent (SNP) | VAF 19/50 reads (38%) | catalogued as rs756826832, COSV56644130; called by muse, mutect2, varscan2
- ADAMTS13 | c.1947C>T p.L649= | Silent (SNP) | VAF 6/25 reads (24%) | catalogued as COSV100747112; called by muse, mutect2, varscan2
- ADAMTS9 | c.3885C>T p.C1295= | Silent (SNP) | VAF 74/167 reads (44%) | catalogued as COSV99899618; called by muse, mutect2, varscan2
- ANKRD29 | c.633C>T p.G211= | Silent (SNP) | VAF 8/21 reads (38%) | catalogued as COSV99409202; called by muse, mutect2, varscan2
- ANKRD6 | c.273C>T p.I91= | Silent (SNP) | VAF 3/17 reads (18%) | catalogued as rs780694454, COSV60235157; called by muse, mutect2
- ANOS1 | c.379C>T p.L127= | Silent (SNP) | VAF 15/52 reads (29%) | catalogued as rs1031088379, COSV52915771, COSV99390985; called by muse, mutect2, varscan2
- AOC3 | c.2181G>A p.G727= | Silent (SNP) | VAF 35/76 reads (46%) | catalogued as COSV100396090; called by muse, mutect2, varscan2
- ARFGAP2 | c.864G>A p.E288= | Silent (SNP) | VAF 55/141 reads (39%) | catalogued as COSV100125569; called by muse, mutect2, varscan2
- ARHGAP44 | c.1335C>T p.F445= | Silent (SNP) | VAF 15/38 reads (39%) | catalogued as COSV52389439; called by muse, mutect2, varscan2
- BAG6 | c.342C>T p.P114= | Silent (SNP) | VAF 66/261 reads (25%) | catalogued as COSV99277191; called by muse, mutect2, varscan2
- BRCA1 | c.4969C>T p.L1657= | Silent (SNP) | VAF 40/98 reads (41%) | catalogued as COSV100524381; called by muse, mutect2, varscan2
- C6orf201 | c.168G>A p.P56= | Silent (SNP) | VAF 35/121 reads (29%) | catalogued as rs748978684, COSV60985757, COSV60988374; called by muse, mutect2, varscan2
- CACNA1D | c.4536C>T p.I1512= (on ENST00000350061 / NM_001128840.3; = p.I1532= on NM_000720.4) | Silent (SNP) | VAF 33/70 reads (47%) | catalogued as COSV55456162; called by muse, mutect2, varscan2
- CAPZA3 | c.138C>T p.H46= | Silent (SNP) | VAF 44/84 reads (52%) | catalogued as COSV56852833; called by muse, mutect2, varscan2
- CCDC88B | c.2859C>T p.F953= | Silent (SNP) | VAF 4/16 reads (25%) | catalogued as COSV100105544; called by muse, mutect2
- CCNB3 | c.3615C>T p.L1205= | Silent (SNP) | VAF 51/98 reads (52%) | catalogued as COSV52069402, COSV52078647; called by muse, mutect2, varscan2
- CHRNA1 | c.226C>T p.L76= | Silent (SNP) | VAF 42/80 reads (53%) | catalogued as COSV99650491; called by muse, mutect2, varscan2
- CILP2 | c.2250C>T p.T750= | Silent (SNP) | VAF 11/17 reads (65%) | catalogued as rs756830121, COSV99364808; called by muse, mutect2, varscan2
- CLDN2 | c.399C>T p.F133= | Silent (SNP) | VAF 70/155 reads (45%) | catalogued as rs1324491659, COSV100390121; called by muse, mutect2, varscan2
- CLDN2 | c.639A>G p.Q213= | Silent (SNP) | VAF 74/168 reads (44%) | catalogued as rs903761545, COSV100390122; called by muse, mutect2, varscan2
- CLEC18A | c.39C>T p.L13= | Silent (SNP) | VAF 14/52 reads (27%) | catalogued as COSV99846971; called by mutect2, varscan2
- CLEC4D | c.48C>T p.P16= | Silent (SNP) | VAF 36/79 reads (46%) | catalogued as COSV100223045; called by muse, mutect2, varscan2
- CNPPD1 | c.276C>T p.S92= | Silent (SNP) | VAF 8/54 reads (15%) | catalogued as COSV99811582; called by muse, mutect2, varscan2
- CNTRL | c.2751C>T p.H917= | Silent (SNP) | VAF 16/42 reads (38%) | catalogued as COSV99442729; called by muse, mutect2, varscan2
- COL6A3 | c.2772G>A p.Q924= | Silent (SNP) | VAF 24/95 reads (25%) | catalogued as COSV99798980; called by muse, mutect2, varscan2
- DBF4B | c.273C>T p.S91= | Silent (SNP) | VAF 30/78 reads (38%) | catalogued as COSV100154545; called by muse, mutect2, varscan2
- DDX19A | c.243G>A p.R81= | Silent (SNP) | VAF 143/179 reads (80%) | catalogued as COSV100156316; called by muse, mutect2, varscan2
- DEFB128 | c.99G>A p.R33= | Silent (SNP) | VAF 113/231 reads (49%) | catalogued as COSV100544449; called by muse, mutect2, varscan2
- DMBX1 | c.480C>T p.T160= | Silent (SNP) | VAF 44/148 reads (30%) | catalogued as rs776705033, COSV100760805; called by muse, mutect2, varscan2
- DNAH2 | c.7275C>T p.I2425= | Silent (SNP) | VAF 38/45 reads (84%) | catalogued as rs201346992, COSV101209405; called by muse, mutect2, varscan2
- DNAH5 | c.5697C>T p.I1899= | Silent (SNP) | VAF 20/75 reads (27%) | catalogued as COSV54244631, COSV54247801; called by muse, mutect2, varscan2
- DNHD1 | c.1756C>T p.L586= | Silent (SNP) | VAF 46/92 reads (50%) | catalogued as COSV99600327; called by muse, mutect2, varscan2
- DSG1 | c.1809G>A p.Q603= | Silent (SNP) | VAF 28/75 reads (37%) | catalogued as COSV99936129; called by muse, mutect2, varscan2
- EGF | c.1503A>G p.T501= | Silent (SNP) | VAF 88/182 reads (48%) | catalogued as COSV99491056; called by muse, mutect2, varscan2
- EMID1 | c.771C>T p.P257= | Silent (SNP) | VAF 16/35 reads (46%) | catalogued as rs754539460, COSV100469069; called by muse, mutect2, varscan2
- EPHA7 | c.2832C>T p.F944= | Silent (SNP) | VAF 26/62 reads (42%) | catalogued as COSV100993131; called by muse, mutect2, varscan2
- EPHA8 | c.261C>T p.S87= | Silent (SNP) | VAF 56/136 reads (41%) | catalogued as rs1233591828, COSV99385030; called by muse, mutect2, varscan2
- FAM214A | c.2829C>T p.S943= | Silent (SNP) | VAF 30/102 reads (29%) | catalogued as COSV99958058; called by muse, mutect2, varscan2
- FAM47B | c.1635G>A p.R545= | Silent (SNP) | VAF 84/197 reads (43%) | catalogued as COSV100264385; called by muse, mutect2, varscan2
- FAM90A1 | c.51C>T p.A17= | Silent (SNP) | VAF 6/34 reads (18%) | catalogued as rs1229030115, COSV100274352; called by muse, mutect2, varscan2
- FANCM | c.1302C>T p.I434= | Silent (SNP) | VAF 15/72 reads (21%) | catalogued as COSV99951158; called by muse, mutect2, varscan2
- FARP1 | c.1338G>A p.A446= | Silent (SNP) | VAF 13/74 reads (18%) | catalogued as COSV60348378; called by muse, mutect2, varscan2
- FGD5 | c.3498C>T p.R1166= | Silent (SNP) | VAF 30/76 reads (39%) | catalogued as rs1010360975, COSV99548301; called by muse, mutect2, varscan2
- FGF8 | c.315C>T p.I105= (on ENST00000344255 / NM_033164.4; = p.I87= on NM_006119.6) | Silent (SNP) | VAF 23/38 reads (61%) | catalogued as rs367853216; called by muse, mutect2, varscan2
- FLVCR1 | c.1314C>T p.F438= | Silent (SNP) | VAF 39/89 reads (44%) | catalogued as COSV100875073; called by muse, mutect2, varscan2
- GABRE | c.483G>A p.K161= | Silent (SNP) | VAF 50/103 reads (49%) | catalogued as COSV100944295; called by muse, mutect2, varscan2
- GGH | c.445T>C p.L149= | Silent (SNP) | VAF 21/68 reads (31%) | catalogued as COSV99478893; called by muse, mutect2, varscan2
- GIMAP4 | c.444C>T p.F148= | Silent (SNP) | VAF 36/168 reads (21%) | catalogued as COSV55433255; called by muse, mutect2, varscan2
- GLIPR1L2 | c.369C>T p.G123= | Silent (SNP) | VAF 29/63 reads (46%) | catalogued as COSV100248638; called by muse, mutect2, varscan2
- GLIS1 | c.828G>A p.L276= | Silent (SNP) | VAF 28/75 reads (37%) | catalogued as rs952330882, COSV100390217; called by muse, mutect2, varscan2
- GPR141 | c.120C>T p.F40= | Silent (SNP) | VAF 88/153 reads (58%) | catalogued as rs770073216, COSV57734010; called by muse, mutect2, varscan2
- GPRC5B | c.207C>T p.I69= | Silent (SNP) | VAF 37/88 reads (42%) | catalogued as COSV56025096; called by muse, mutect2, varscan2
- GPRIN2 | c.747C>T p.A249= | Silent (SNP) | VAF 28/86 reads (33%) | catalogued as COSV100966412; called by muse, mutect2, varscan2
- GRID1 | c.801C>T p.I267= | Silent (SNP) | VAF 40/53 reads (75%) | catalogued as COSV60017428; called by muse, mutect2, varscan2
- GSDMA | c.1263C>T p.D421= | Silent (SNP) | VAF 39/103 reads (38%) | catalogued as COSV99227869; called by muse, mutect2, varscan2
- GUCY1A2 | c.903C>T p.I301= | Silent (SNP) | VAF 26/57 reads (46%) | catalogued as COSV56487431; called by muse, mutect2, varscan2
- H1-7 | c.681G>A p.P227= | Silent (SNP) | VAF 17/43 reads (40%) | catalogued as rs752051629, COSV58602062, COSV58602149; called by muse, mutect2, varscan2
- HECTD4 | c.5676C>T p.I1892= | Silent (SNP) | VAF 35/60 reads (58%) | catalogued as rs770979331, COSV101107763; called by muse, mutect2, varscan2
- HTR7 | c.939G>A p.R313= | Silent (SNP) | VAF 24/34 reads (71%) | catalogued as rs866678905, COSV99519756; called by muse, mutect2, varscan2
- IGHV4-31 | c.21C>T p.F7= | Silent (SNP) | VAF 11/78 reads (14%) | catalogued as rs1327842841; called by muse, mutect2, varscan2
- IGKV1-12 | c.60C>T p.S20= | Silent (SNP) | VAF 24/189 reads (13%) | catalogued as rs765039388; called by muse, mutect2
- ITIH5 | c.1089C>T p.H363= | Silent (SNP) | VAF 30/74 reads (41%) | catalogued as COSV99904907; called by muse, mutect2, varscan2
- ITPR3 | c.5253G>A p.Q1751= | Silent (SNP) | VAF 53/189 reads (28%) | catalogued as COSV100967503; called by muse, mutect2, varscan2
- KCNC4 | c.648C>T p.F216= | Silent (SNP) | VAF 10/16 reads (63%) | catalogued as rs957197978, COSV100873635; called by muse, mutect2, varscan2
- KLK6 | c.702G>A p.T234= | Silent (SNP) | VAF 70/181 reads (39%) | catalogued as rs372369976; called by muse, mutect2, varscan2
- KRT31 | c.729G>A p.V243= | Silent (SNP) | VAF 50/123 reads (41%) | catalogued as COSV99289818; called by muse, mutect2, varscan2
- LCE3D | c.72G>A p.K24= | Silent (SNP) | VAF 62/214 reads (29%) | catalogued as rs375722640; called by muse, mutect2, varscan2
- LPXN | c.600C>T p.P200= | Silent (SNP) | VAF 104/246 reads (42%) | catalogued as rs927059502, COSV101223064; called by muse, mutect2, varscan2
- LRRC18 | c.429G>A p.L143= | Silent (SNP) | VAF 12/18 reads (67%) | catalogued as COSV99629734; called by muse, mutect2, varscan2
- LRRC56 | c.1251C>T p.V417= | Silent (SNP) | VAF 15/32 reads (47%) | catalogued as rs1179160682, COSV99530285; called by muse, mutect2, varscan2
- MAP3K19 | c.3105G>A p.R1035= | Silent (SNP) | VAF 41/66 reads (62%) | catalogued as COSV59642729; called by muse, mutect2, varscan2
- MCM2 | c.2559C>T p.A853= | Silent (SNP) | VAF 53/108 reads (49%) | catalogued as COSV99413214; called by muse, mutect2, varscan2
- MEI1 | c.3351C>T p.D1117= | Silent (SNP) | VAF 9/35 reads (26%) | catalogued as COSV100300054; called by muse, mutect2, varscan2
- MICAL3 | c.1188C>T p.V396= | Silent (SNP) | VAF 31/79 reads (39%) | catalogued as rs766291618, COSV99261885; called by muse, mutect2, varscan2
- MIDEAS | c.2955C>T p.I985= | Silent (SNP) | VAF 13/40 reads (33%) | catalogued as COSV54093803; called by muse, mutect2, varscan2
- MIOX | c.114C>T p.D38= | Silent (SNP) | VAF 43/103 reads (42%) | catalogued as rs568435187, COSV99326946; called by muse, mutect2, varscan2
- MYH13 | c.1201C>T p.L401= | Silent (SNP) | VAF 27/72 reads (38%) | catalogued as COSV52824956, COSV52832796; called by muse, mutect2, varscan2
- MYH15 | c.468C>T p.V156= | Silent (SNP) | VAF 30/71 reads (42%) | catalogued as COSV56311409; called by muse, mutect2, varscan2
- MYH2 | c.672C>T p.I224= | Silent (SNP) | VAF 45/116 reads (39%) | catalogued as COSV55445693; called by muse, mutect2, varscan2
- NAT10 | c.471C>T p.L157= | Silent (SNP) | VAF 31/110 reads (28%) | catalogued as COSV99140163; called by muse, mutect2, varscan2
- NDST4 | c.252G>A p.V84= | Silent (SNP) | VAF 39/79 reads (49%) | catalogued as rs745360958, COSV99996752; called by muse, mutect2, varscan2
- NFS1 | c.423C>T p.F141= | Silent (SNP) | VAF 74/202 reads (37%) | catalogued as COSV100148765; called by muse, mutect2
- NPAP1 | c.285G>A p.R95= | Silent (SNP) | VAF 22/49 reads (45%) | catalogued as COSV61510930; called by muse, mutect2, varscan2
- NPSR1 | c.468C>T p.F156= | Silent (SNP) | VAF 58/96 reads (60%) | catalogued as COSV62196839; called by muse, mutect2, varscan2
- OBSCN | c.4551G>A p.G1517= | Silent (SNP) | VAF 74/142 reads (52%) | catalogued as COSV99479981; called by muse, mutect2, varscan2
- OR10G9 | c.882G>A p.V294= | Silent (SNP) | VAF 45/134 reads (34%) | catalogued as rs1443233258, COSV66685906; called by muse, mutect2, varscan2
- OR14I1 | c.708C>T p.F236= | Silent (SNP) | VAF 64/138 reads (46%) | catalogued as rs763832952, COSV100700488; called by muse, mutect2, varscan2
- OR2A12 | c.849C>T p.I283= | Silent (SNP) | VAF 360/605 reads (60%) | catalogued as COSV68821968; called by muse, mutect2, varscan2
- OR5A1 | c.609C>T p.F203= | Silent (SNP) | VAF 102/218 reads (47%) | catalogued as rs1462065071, COSV100118381; called by muse, mutect2, varscan2
- OR5P2 | c.741C>T p.F247= | Silent (SNP) | VAF 38/90 reads (42%) | catalogued as COSV100271371; called by muse, mutect2, varscan2
- OR6A2 | c.615C>T p.F205= | Silent (SNP) | VAF 68/174 reads (39%) | catalogued as rs865944663, COSV60264638; called by muse, mutect2, varscan2
- OR7G2 | c.468C>T p.I156= | Silent (SNP) | VAF 22/29 reads (76%) | called by muse, mutect2, varscan2
- OVCH2 | c.660G>A p.G220= | Silent (SNP) | VAF 10/21 reads (48%) | catalogued as COSV101491904; called by muse, mutect2, varscan2
- P4HA3 | c.795G>A p.R265= | Silent (SNP) | VAF 76/180 reads (42%) | catalogued as COSV100525760, COSV59043759; called by muse, mutect2, varscan2
- PANK4 | c.396C>T p.D132= | Silent (SNP) | VAF 51/133 reads (38%) | catalogued as COSV101022457; called by muse, mutect2, varscan2
- PCDHGA2 | c.2389C>T p.L797= | Silent (SNP) | VAF 46/57 reads (81%) | catalogued as COSV99540084; called by muse, mutect2, varscan2
- PCDHGA8 | c.1356C>T p.F452= | Silent (SNP) | VAF 19/26 reads (73%) | catalogued as COSV99038490, COSV99540089; called by muse, mutect2, varscan2
- PCNX4 | c.921C>T p.F307= (on ENST00000406854 / NM_001330177.2; = p.F73= on NM_022495.5) | Silent (SNP) | VAF 24/49 reads (49%) | catalogued as COSV100470445; called by muse, mutect2, varscan2
- PKD1L1 | c.7591C>T p.L2531= | Silent (SNP) | VAF 19/31 reads (61%) | catalogued as COSV99219282; called by muse, mutect2, varscan2
- PLA2G4D | c.2301C>T p.T767= | Silent (SNP) | VAF 19/47 reads (40%) | catalogued as COSV99299763; called by muse, mutect2, varscan2
- PLEKHG7 | c.123C>T p.A41= | Silent (SNP) | VAF 31/68 reads (46%) | catalogued as COSV101188861; called by muse, mutect2, varscan2
- PLPP4 | c.621C>T p.S207= | Silent (SNP) | VAF 76/90 reads (84%) | catalogued as rs901815640, COSV64829590, COSV64829684; called by muse, mutect2, varscan2
- PLXNA1 | c.2085C>T p.F695= | Silent (SNP) | VAF 35/98 reads (36%) | catalogued as rs1207586986, COSV99303303; called by muse, mutect2, varscan2
- PRDM1 | c.1167C>T p.Y389= | Silent (SNP) | VAF 46/63 reads (73%) | catalogued as COSV100958842; called by muse, mutect2, varscan2
- PRKCH | c.876C>T p.A292= | Silent (SNP) | VAF 41/90 reads (46%) | catalogued as COSV100273419; called by muse, mutect2, varscan2
- PSAT1 | c.792C>T p.A264= | Silent (SNP) | VAF 74/143 reads (52%) | catalogued as rs371935677; ClinVar: likely benign; called by muse, mutect2, varscan2
- PTPRC | c.1359G>A p.T453= | Silent (SNP) | VAF 21/54 reads (39%) | catalogued as rs776904542, COSV61407101; called by muse, mutect2, varscan2
- PTPRC | c.3825G>A p.K1275= | Silent (SNP) | VAF 39/105 reads (37%) | catalogued as COSV100722760; called by muse, mutect2, varscan2
- PTPRD | c.4815C>T p.I1605= | Silent (SNP) | VAF 87/200 reads (44%) | catalogued as COSV61958848; called by muse, mutect2, varscan2
- PTPRG | c.1587C>T p.F529= | Silent (SNP) | VAF 27/45 reads (60%) | catalogued as COSV99875377; called by muse, mutect2, varscan2
- RAP1GAP2 | c.1194C>T p.S398= | Silent (SNP) | VAF 22/32 reads (69%) | catalogued as COSV54588631; called by muse, mutect2, varscan2
- RASSF9 | c.159C>T p.I53= | Silent (SNP) | VAF 29/104 reads (28%) | catalogued as COSV100771419; called by muse, mutect2, varscan2
- RBM47 | c.426C>T p.L142= | Silent (SNP) | VAF 29/84 reads (35%) | catalogued as rs755990777, COSV55941033; called by muse, mutect2, varscan2
- RGP1 | c.834C>T p.V278= | Silent (SNP) | VAF 12/42 reads (29%) | catalogued as COSV100960243; called by muse, mutect2, varscan2
- RIMS2 | c.4350G>A p.K1450= (on ENST00000666250 / NM_001348490.2; = p.K1021= on NM_014677.5 and 7 other RefSeq transcripts) | Silent (SNP) | VAF 25/49 reads (51%) | catalogued as rs1010891668, COSV51682501; called by muse, mutect2, varscan2
- RNF8 | c.1266C>T p.F422= | Silent (SNP) | VAF 59/247 reads (24%) | catalogued as COSV100009663; called by muse, mutect2, varscan2
- RPAP1 | c.354C>T p.A118= | Silent (SNP) | VAF 17/40 reads (43%) | catalogued as rs756345054, COSV58540657; called by muse, mutect2, varscan2
- SCIN | c.1149G>A p.Q383= (on ENST00000297029 / NM_001112706.3; = p.Q136= on NM_033128.3) | Silent (SNP) | VAF 10/23 reads (43%) | catalogued as COSV51698489, COSV99764939; called by muse, mutect2, varscan2
- SCN5A | c.5091C>T p.F1697= (on ENST00000333535 / NM_198056.3; = p.F1696= on NM_000335.5) | Silent (SNP) | VAF 90/255 reads (35%) | catalogued as rs762929897, COSV61119855; ClinVar: likely benign; called by muse, mutect2, varscan2
- SCN8A | c.3006C>T p.I1002= | Silent (SNP) | VAF 19/37 reads (51%) | catalogued as COSV100633948; called by muse, mutect2, varscan2
- SESN3 | c.559C>T p.L187= | Silent (SNP) | VAF 61/154 reads (40%) | catalogued as COSV99060070, COSV99565707; called by muse, mutect2, varscan2
- SLC1A5 | c.1368C>T p.I456= | Silent (SNP) | VAF 50/98 reads (51%) | catalogued as COSV69467527, COSV69467695; called by muse, mutect2, varscan2
- SLC30A10 | c.696G>A p.K232= | Silent (SNP) | VAF 24/64 reads (38%) | catalogued as COSV100751529; called by muse, mutect2, varscan2
- SLC34A1 | c.54C>T p.V18= | Silent (SNP) | VAF 15/21 reads (71%) | catalogued as COSV60996399; called by muse, mutect2, varscan2
- SLC44A1 | c.312C>T p.N104= | Silent (SNP) | VAF 47/146 reads (32%) | catalogued as COSV101029432; called by muse, mutect2, varscan2
- SLC4A1AP | c.1986G>A p.E662= | Silent (SNP) | VAF 21/72 reads (29%) | catalogued as rs1311570197, COSV100389442; called by muse, mutect2, varscan2
- SPEG | c.960C>T p.S320= | Silent (SNP) | VAF 16/24 reads (67%) | catalogued as rs1027561034, COSV100404762; called by muse, mutect2, varscan2
- SYNJ2 | c.3048A>G p.E1016= | Silent (SNP) | VAF 179/237 reads (76%) | catalogued as COSV100840309; called by muse, mutect2, varscan2
- TBC1D2 | c.2316C>T p.P772= | Silent (SNP) | VAF 48/118 reads (41%) | catalogued as COSV100579953; called by muse, mutect2, varscan2
- TBXAS1 | c.1188G>A p.V396= | Silent (SNP) | VAF 81/239 reads (34%) | catalogued as COSV99695495; called by muse, mutect2, varscan2
- TET3 | c.3084C>T p.V1028= | Silent (SNP) | VAF 8/10 reads (80%) | catalogued as rs373633219; called by muse, mutect2, varscan2
- TGM5 | c.1533C>T p.F511= (on ENST00000220420 / NM_201631.4; = p.F429= on NM_004245.4) | Silent (SNP) | VAF 23/58 reads (40%) | catalogued as COSV99589055; called by muse, mutect2, varscan2
- TKTL1 | c.108C>T p.I36= | Silent (SNP) | VAF 121/357 reads (34%) | catalogued as COSV99474016; called by muse, mutect2, varscan2
- TMEM176A | c.628C>T p.L210= | Silent (SNP) | VAF 93/157 reads (59%) | catalogued as COSV99133794; called by muse, mutect2, varscan2
- TMEM94 | c.1662G>A p.E554= | Silent (SNP) | VAF 30/79 reads (38%) | catalogued as COSV100050555; called by muse, mutect2, varscan2
- TMOD3 | c.645C>T p.T215= | Silent (SNP) | VAF 28/92 reads (30%) | catalogued as COSV100419125; called by muse, mutect2, varscan2
- TMPRSS11F | c.327C>T p.I109= | Silent (SNP) | VAF 11/14 reads (79%) | catalogued as COSV100678615; called by muse, mutect2, varscan2
- TRAV13-1 | c.30C>T p.F10= | Silent (SNP) | VAF 32/60 reads (53%) | called by muse, mutect2, varscan2
- TRAV19 | c.201C>T p.F67= | Silent (SNP) | VAF 16/32 reads (50%) | catalogued as rs140297772; called by muse, mutect2, varscan2
- TRIM15 | c.357G>A p.L119= | Silent (SNP) | VAF 26/99 reads (26%) | catalogued as COSV100938836; called by muse, mutect2, varscan2
- TRIM71 | c.2001C>T p.I667= | Silent (SNP) | VAF 32/69 reads (46%) | catalogued as COSV67470340; called by muse, mutect2, varscan2
- TRIO | c.8280C>T p.I2760= | Silent (SNP) | VAF 63/144 reads (44%) | catalogued as rs776118053, COSV100702629; called by muse, mutect2, varscan2
- TSPAN10 | c.717C>T p.F239= (on ENST00000574882 / NM_001290212.1; = p.F201= on NM_031945.4) | Silent (SNP) | VAF 12/35 reads (34%) | catalogued as COSV100148563; called by muse, mutect2, varscan2
- TTLL6 | c.1371C>T p.F457= (on ENST00000393382 / NM_001130918.3; = p.F150= on NM_173623.3) | Silent (SNP) | VAF 26/49 reads (53%) | catalogued as COSV64976323, COSV64977569; called by muse, mutect2, varscan2
- USB1 | c.54C>T p.S18= | Silent (SNP) | VAF 12/26 reads (46%) | catalogued as COSV99540229; called by muse, varscan2
- VSTM2A | c.480C>T p.F160= | Silent (SNP) | VAF 14/45 reads (31%) | catalogued as rs781550989, COSV56495044; called by muse, mutect2, varscan2
- WDR6 | c.1962T>G p.G654= | Silent (SNP) | VAF 44/86 reads (51%) | catalogued as COSV100556499; called by muse, mutect2, varscan2
- XYLT1 | c.2259C>T p.F753= | Silent (SNP) | VAF 31/86 reads (36%) | catalogued as COSV99762094; called by muse, mutect2, varscan2
- ZBED9 | c.1452C>T p.F484= | Silent (SNP) | VAF 41/135 reads (30%) | catalogued as COSV101509281; called by muse, mutect2, varscan2
- ZBTB12 | c.649C>T p.L217= | Silent (SNP) | VAF 77/297 reads (26%) | catalogued as COSV64993850; called by muse, mutect2, varscan2
- ZC3H12A | c.30C>T p.V10= | Silent (SNP) | VAF 92/190 reads (48%) | catalogued as rs199814706, COSV100897725; called by muse, mutect2, varscan2
- ZC3H12B | c.1866G>A p.Q622= | Silent (SNP) | VAF 8/23 reads (35%) | catalogued as COSV100161810; called by muse, mutect2, varscan2
- ZCCHC12 | c.759G>A p.P253= | Silent (SNP) | VAF 31/77 reads (40%) | catalogued as COSV59571485; called by muse, mutect2, varscan2
- ZDBF2 | c.2238C>T p.S746= | Silent (SNP) | VAF 48/176 reads (27%) | catalogued as COSV100984996; called by muse, mutect2, varscan2
- ZFAT | c.414C>T p.I138= | Silent (SNP) | VAF 37/95 reads (39%) | catalogued as rs200807830, COSV64734748; called by muse, mutect2, varscan2
- ZFP36L1 | c.834C>T p.L278= | Silent (SNP) | VAF 88/197 reads (45%) | catalogued as rs760082533, COSV60544523; called by muse, mutect2, varscan2
- ZMIZ2 | c.2253C>T p.F751= | Silent (SNP) | VAF 45/131 reads (34%) | catalogued as COSV99536958; called by muse, mutect2, varscan2
- ZNF318 | c.2952C>T p.I984= | Silent (SNP) | VAF 100/250 reads (40%) | catalogued as rs748185425, COSV100546292, COSV58932373, COSV58936107; called by muse, mutect2, varscan2
- ZNF449 | c.288G>A p.E96= | Silent (SNP) | VAF 31/70 reads (44%) | catalogued as COSV100203008; called by muse, mutect2, varscan2
- ZNF473 | c.1227G>A p.G409= | Silent (SNP) | VAF 56/124 reads (45%) | catalogued as rs1434892052, COSV99568888; called by muse, mutect2, varscan2
- ZNF503 | c.1701C>T p.A567= | Silent (SNP) | VAF 16/20 reads (80%) | catalogued as rs1345852864, COSV100998011; called by muse, mutect2, varscan2
- AC024940.1 | n.2934G>A | RNA (SNP) | VAF 37/162 reads (23%) | called by muse, mutect2
- ANKRD13C | chr1:70355202 C>T | 5'Flank (SNP) | VAF 3/17 reads (18%) | catalogued as COSV52032379; called by muse, mutect2
- BCR | c.1279+17103C>T | Intron (SNP) | VAF 63/177 reads (36%) | called by muse, mutect2, varscan2
- FOLR1 | c.*2C>T | 3'UTR (SNP) | VAF 17/42 reads (40%) | catalogued as rs751976542, COSV100398565; called by muse, mutect2, varscan2
- GUK1 | c.-3+504C>T | Intron (SNP) | VAF 12/22 reads (55%) | called by muse, mutect2, varscan2
- HLA-DRB9 | n.122A>C | RNA (SNP) | VAF 22/157 reads (14%) | called by muse, mutect2, varscan2
- MAPK10 | c.-105A>G | 5'UTR (SNP) | VAF 75/170 reads (44%) | catalogued as COSV100174657; called by muse, mutect2, varscan2
- PDLIM5 | c.920+574C>T | Intron (SNP) | VAF 14/28 reads (50%) | catalogued as COSV100523511; called by muse, mutect2, varscan2
- SRSF6 | c.257-567C>T | Intron (SNP) | VAF 9/54 reads (17%) | called by muse, mutect2, varscan2
- ZNF322P1 | n.943C>T | RNA (SNP) | VAF 13/26 reads (50%) | catalogued as rs868450416; called by mutect2, varscan2
